Gene-level copy-number profile of tumor specimen TCGA-61-1738-01A from TCGA case TCGA-61-1738, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 60.1 years (21,965 days).
Specimen TCGA-61-1738-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.217579ca-cc7a-4c54-a669-1b511735f20e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-1738-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/df8883e7-dad9-441b-9735-0be13da513c1

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 29; copy number 2: 10,555; copy number 3: 12,544; copy number 4: 32,681; copy number 5: 1,156; copy number 6: 1,836; copy number 7: 79; copy number 8: 471; copy number 9: 141; copy number 10: 57; copy number 11: 112; copy number 12: 14; copy number 13: 63; copy number 14: 12; copy number 16: 5; copy number 17: 10; copy number 18: 18; copy number 23: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-61-1738-01A-01D-0577-01): tumor purity 0.93, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 443 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:115,904,855–116,671,827, 21 genes, copy number 11 (within-gene range 6–11): LINC01649, AL357137.1, SLC22A15, AL365318.1, MAB21L3, LINC01779, U3, AL355538.1, ATP1A1, ATP1A1-AS1, RNU6-817P, LINC01762, AL136376.1, Y_RNA, AL390066.1, AL390066.2, CD58, NAP1L4P1, MIR548AC, IGSF3, MIR320B1.
- chr1:116,909,149–117,700,242, 21 genes, copy number 17–23: AL157904.1, PTGFRN, RNA5SP55, CD101, AL445231.1, TTF2, MIR942, TRIM45, RPS15AP9, VTCN1, Metazoa_SRP, LINC01525, AL358072.1, MAN1A2, AL157902.2, VPS25P1, AL157902.1, TENT5C, VDAC2P3, AL390877.1, AL390877.2.
- chr1:150,321,479–151,459,494, 63 genes, copy number 13 (broad region; genes not listed).
- chr1:219,173,869–221,563,653, 51 genes, copy number 9: LYPLAL1, RIMKLBP2, AL360093.1, AC096642.1, AC096642.2, LYPLAL1-AS1, AL356364.1, ZC3H11B, SLC30A10, RNA5SP76, U3, EPRS1, BPNT1, IARS2, MIR215, MIR194-1, RPS15AP12, RAB3GAP2, MIR664A, SNORA36B, SNX2P1, KF455155.1, MORF4L1P1, AURKAP1, XRCC6P3, AL451081.2, AL451081.1, AC096644.3, AC096644.2, AC096644.1, PRELID3BP1, LINC02779, MARK1, RN7SL464P, HDAC1P2, C1orf115, MTARC2, MTARC1, AL445423.3, RNU6ATAC35P, AL445423.2, AL445423.1, LINC01352, HLX-AS1, HLX, AL445466.1, LINC02817, AL360013.2, AL360013.3, AL360013.1, AL360013.4.
- chr3:168,858,659–169,038,416, 5 genes, copy number 12: RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997.
- chr3:176,415,439–178,385,479, 24 genes, copy number 11–14 (within-gene range 6–14): LINC01208, MIR7977, RNA5SP147, LINC01209, MTND5P15, TBL1XR1, TBL1XR1-AS1, Y_RNA, RNU6-681P, LINC00501, ASS1P7, AC117465.1, LINC00578, RN7SKP52, AC026355.3, AC026355.1, AC026355.2, AC026355.4, LINC02015, AC007953.1, AC007953.2, RNU6-1120P, AC110992.1, AC117453.1.
- chr3:195,514,428–197,573,323, 87 genes, copy number 11 (broad region; genes not listed).
- chr3:197,580,344–197,580,629, 1 gene, copy number 11: AC132008.1.
- chr4:784,957–1,218,591, 19 genes, copy number 9 (within-gene range 3–9): CPLX1, AC139887.3, AC139887.5, GAK, TMEM175, DGKQ, SLC26A1, IDUA, FGFRL1, AC019103.1, RNF212, AC092535.3, AC092535.4, TMED11P, AC092535.1, AC092535.2, SPON2, AC092535.5, CTBP1-AS.
- chr7:81,175,508–81,770,438, 8 genes, copy number 9: AC005008.2, AC005008.1, AC004866.1, AC004866.2, EIF4EP4, AC008163.1, DDX43P3, HGF.
- chr11:121,238,304–121,633,763, 7 genes, copy number 9: AP001124.1, RPS4XP12, SC5D, BMPR1AP2, AP002365.1, AP000977.1, SORL1.
- chr14:50,397,013–51,385,603, 30 genes, copy number 9 (within-gene range 4–9): AL359397.1, MAP4K5, AL118556.1, Y_RNA, AL118556.2, ATL1, SNRPGP1, SAV1, RN7SL452P, AL606834.1, ZFP64P1, NIN, AL606834.2, AL133485.2, AL133485.3, AL133485.1, AL358334.1, PYGL, ABHD12B, AL358334.3, AL358334.2, TRIM9, AL358334.4, AL591770.1, TMX1, SNORA70, Y_RNA, LINC00519, LINC00640, AL358332.1.
- chr14:67,819,779–68,736,678, 14 genes, copy number 10–16: RAD51B, AL133370.2, AL133370.1, RN7SL706P, RN7SL108P, AL122013.1, PPIAP6, AL121820.3, AL121820.2, AL121820.1, RPL12P7, AL133313.1, AL132986.1, RNU6-921P.
- chr14:80,954,989–81,743,749, 20 genes, copy number 9: TSHR, BHLHB9P1, RPL17P3, AC007262.1, AC007262.2, NMNAT1P1, AL136040.2, GTF2A1, SNORA79, AL136040.1, DYNLL1P1, UNGP3, STON2, AL121769.1, DYNLL1P2, LINC02308, SEL1L, LINC01467, EEF1A1P2, LINC02311.
- chr14:81,777,016–81,777,613, 1 gene, copy number 9: RPL9P6.
- chr17:799,310–1,003,671, 5 genes, copy number 9 (within-gene range 4–9): NXN, AC087392.2, AC087392.1, AC036164.1, TIMM22.
- chr17:39,461,486–39,877,896, 18 genes, copy number 18 (within-gene range 4–18): CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2.
- chr17:75,205,659–76,072,517, 48 genes, copy number 10: NUP85, GGA3, MRPS7, MIF4GD, AC022211.2, SLC25A19, GRB2, AC011933.1, AC011933.4, AC011933.2, AC011933.3, MIR3678, RNU6-938P, Y_RNA, TMEM94, MIR6785, CASKIN2, TSEN54, LLGL2, MYO15B, RECQL5, SMIM5, SMIM6, SAP30BP, AC087749.2, AC087749.1, ITGB4, GALK1, H3-3B, MIR4738, UNK, AC087289.1, UNC13D, WBP2, TRIM47, AC087289.5, TRIM65, AC087289.2, MRPL38, AC087289.3, FBF1, ACOX1, AC087289.4, TEN1-CDK3, TEN1, CDK3, EVPL, SRP68.

Autosomal genes at a single copy (total copy number 1): 29. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
